Somatic mutation profile of tumor specimen 0DE7FN from CCDI case PBBPRL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.4 years (4,519 days).
Specimen 0DE7FN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d54caab1-5a25-466f-95da-4a42d11ba586.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b46d83ca-e8ad-41ec-8a3c-b80ab8e807b6

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, Silent 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RENBP | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs782052502; called by muse, mutect2, varscan2
- TBC1D25 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs782124960; called by muse, mutect2
- CNTLN | c.612A>T p.L204F | Missense Mutation (SNP) | VAF 55/539 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2
- F5 | c.6016A>G p.I2006V | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZIC2 | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 73/240 reads (30%) | called by muse, mutect2, varscan2
- DSG1 | c.2607C>T p.V869= | Silent (SNP) | VAF 120/374 reads (32%) | catalogued as rs371231511, COSV57137110; called by muse, mutect2, varscan2
- NEURL1B | c.1479G>A p.P493= | Silent (SNP) | VAF 59/327 reads (18%) | catalogued as rs1258223736, COSV63940209; called by muse, mutect2, varscan2
- DCHS2 | n.3510G>A | RNA (SNP) | VAF 65/285 reads (23%) | called by muse, mutect2, varscan2
- DMAC2 | c.433+51T>C | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, varscan2
- DMAC2 | c.433+50G>C | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 7/68 reads (10%) | called by muse, varscan2
